Gene-level copy-number profile of tumor specimen TCGA-BS-A0V8-01A from TCGA case TCGA-BS-A0V8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 68.4 years (24,981 days).
Specimen TCGA-BS-A0V8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.03fb1ece-f53f-45b0-ab35-20d762859ad4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BS-A0V8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c71200f2-a318-4a6e-a1b5-5cda60eeee90

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 536; copy number 2: 15,719; copy number 3: 28,223; copy number 4: 10,691; copy number 5: 1,822; copy number 6: 2,147; copy number 7: 325; copy number 8: 61; copy number 10: 266; copy number 12: 9; copy number 13: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BS-A0V8-01A-11D-A120-01): tumor purity 0.61, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:53,276,760–54,365,634, 1 gene (within-gene range 0–2): AC034268.2.
- chr17:53,822,927–54,961,956, 8 genes (within-gene range 0–1): KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 663 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:3,532,008–3,848,008, 12 genes, copy number 7 (within-gene range 6–7): AC108488.2, RNASEH1, RNASEH1-AS1, AC108488.3, RPS7, COLEC11, AC010907.2, TMSB4XP2, ALLC, GAPDHP48, AC010907.1, DCDC2C.
- chr2:15,166,914–15,950,981, 14 genes, copy number 7–12 (within-gene range 6–12): NBAS, RPS26P18, AC008278.2, DDX1, AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P.
- chr2:30,051,066–30,408,346, 9 genes, copy number 8 (within-gene range 6–8): AC016907.2, AC016907.1, YPEL5, SNORA10B, H3P5, LBH, AC109642.1, LINC01936, AC073255.1.
- chr2:43,886,224–44,772,592, 13 genes, copy number 8: LRPPRC, RNU6-1048P, RN7SL455P, AC019129.1, RNU6-566P, PDSS1P2, AC019129.2, PPM1B, AC013717.1, RPL12P19, SLC3A1, PREPL, CAMKMT.
- chr2:69,594,741–69,827,112, 4 genes, copy number 7–13: RPL36AP16, B3GALNT1P1, ANXA4, AC092431.1.
- chr2:164,213,539–165,436,614, 15 genes, copy number 7: PRPS1P1, CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F, AC019197.1, RNA5SP110, RNA5SP111, SLC38A11, SCN3A, SCN2A, MAPRE1P3, AC011303.1.
- chr6:31,530,219–32,224,067, 97 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr6:34,018,643–35,091,406, 27 genes, copy number 7 (within-gene range 4–7): GRM4, KRT18P9, CYCSP55, HMGA1, MIR6835, SMIM29, AL354740.1, RPL35P2, NUDT3, RPS10-NUDT3, RPS10, PACSIN1, SPDEF, IFITM3P3, ILRUN, RPL7P25, RN7SL200P, AL031577.1, AL451165.2, AL451165.1, AL139100.1, SNRPC, UHRF1BP1, Y_RNA, RNY3P15, TAF11, ANKS1A.
- chr6:35,443,044–36,312,229, 29 genes, copy number 7 (within-gene range 4–7): MKRN6P, FANCE, RPL10A, MIR7111, TEAD3, TULP1, AL033519.4, AL033519.3, FKBP5, AL033519.2, AL033519.5, AL033519.1, MIR5690, AL157823.2, ARMC12, AL157823.1, CLPSL2, CLPSL1, CLPS, LHFPL5, SRPK1, SLC26A8, DPRXP2, MAPK14, Z95152.1, MAPK13, Z84485.1, BRPF3, PNPLA1.
- chr6:150,865,679–151,358,559, 13 genes, copy number 7 (within-gene range 4–7): MTHFD1L, ARL4AP5, RNU6-302P, AL133260.2, AL138733.1, AL133260.1, AL138733.2, RNU6-300P, AL356535.1, AKAP12, RNU6-1247P, RNY4P20, RN7SKP268.
- chr8:28,767,661–29,854,543, 22 genes, copy number 8 (within-gene range 6–8): INTS9, INTS9-AS1, AC040975.1, HMBOX1, Metazoa_SRP, HMBOX1-IT1, RNA5SP260, AC108449.2, KIF13B, AC108449.3, AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1.
- chr8:35,672,195–43,674,591, 189 genes, copy number 10 (broad region; genes not listed).
- chr8:52,939,182–57,244,793, 77 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr10:77,730,766–78,178,186, 15 genes, copy number 8: AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP, POLR3A, RPS24, GNAI2P2, AL731555.1.
- chr10:78,288,059–78,301,003, 2 genes, copy number 8: AC010163.3, AC010163.1.
- chr10:102,898,649–103,517,393, 22 genes, copy number 7 (within-gene range 4–7): AL356608.3, AL356608.1, CNNM2, AL356608.2, NT5C2, RPS15AP29, MARCKSL1P1, ST13P13, RPEL1, INA, PCGF6, RNU11-3P, TAF5, ATP5MD, MIR1307, PDCD11, CALHM2, AL139339.2, AL139339.1, CALHM1, CALHM3, NEURL1-AS1.
- chr17:15,627,960–16,832,830, 68 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr17:17,202,649–18,039,209, 35 genes, copy number 7 (within-gene range 6–7): AC055811.2, FLCN, AC055811.3, ACTG1P24, COPS3, NT5M, RPL13P12, AC073621.1, TSEN15P1, Y_RNA, MED9, RASD1, AC020558.6, PEMT, AC020558.2, RNU6-468P, AC020558.1, AC020558.5, SMCR2, AC020558.3, AC020558.4, RAI1, RAI1-AS1, SMCR5, AC122129.2, SREBF1, MIR6777, MIR33B, TOM1L2, AC122129.1, DRC3, ATPAF2, BRI3P3, AC087163.1, AC087163.2.

Autosomal genes at a single copy (total copy number 1): 536. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
